MMRF case MMRF_1794 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/9b30e273-3fb2-4679-ba9b-06b738f67621

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 79 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 79.5 years (29,052 days); ISS stage: II; Days to last known disease status: 1,088 days (3.0 years); Days to last follow up: 1,088 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 4.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 60.2 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.41 g/L; Beta 2 Microglobulin 4.1 µg/mL; Lactate Dehydrogenase 1.93 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 32 g/L; Total Protein 9.6 g/dL; Glucose 7.15 mmol/L.
- Day 78 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.683 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 2 µg/mL; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 1.93 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 5.34 mmol/L.
- Day 190 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.916 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.545 mg/dL; Immunoglobulin G 6.78 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 2.2 µg/mL; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 6.2 g/dL; Glucose 4.51 mmol/L.
- Day 267 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.26 mg/dL; Immunoglobulin G 6.47 g/L; Immunoglobulin A 0.92 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 375 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 11.4 mmol/L.
- Day 365 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.15 mg/dL; Immunoglobulin G 8.18 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 6.44 mmol/L.
- Day 456 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.44 mg/dL; Immunoglobulin G 5.6 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 3.4 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 103 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.08 mmol/L; Albumin 38 g/L; Total Protein 5.5 g/dL; Glucose 5.56 mmol/L.
- Day 519 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.61 mg/dL; Immunoglobulin G 6.38 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 2.5 µg/mL; Lactate Dehydrogenase 3.87 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 5.6 g/dL; Glucose 5.94 mmol/L.
- Day 617 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.76 mg/dL; Immunoglobulin G 8.93 g/L; Immunoglobulin A 0.94 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 3.1 µg/mL; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 4.73 mmol/L.
- Day 730 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL; Immunoglobulin G 9.33 g/L; Immunoglobulin A 1.05 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 3.52 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 120 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 5.72 mmol/L.
- Day 820 (ECOG 0): Hemoglobin 7.56 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 127 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 5.61 mmol/L.
- Day 932 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.47 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 2.7 µg/mL; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 5.5 mmol/L.
- Day 1,014 (ECOG 0): M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.63 mg/dL; Immunoglobulin G 18.6 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.8 µg/mL; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 7.2 g/dL; Glucose 6.38 mmol/L.
- Day 1,088 (ECOG 0): Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 6.88 mmol/L.

Other clinical attributes
- Day 1: Weight: 66 kg; Height: 152 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1794_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1794_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
